FM case AD950 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Trachea.
https://portal.gdc.cancer.gov/cases/6d4f38db-a97b-4dc0-8dc5-2ac7f2cc5e38

Female, 54.5 years: Adenoid cystic carcinoma (ICD-O-3 8200/3) of the trachea; primary biopsied or resected from the trachea. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
